Somatic mutation profile of tumor specimen TCGA-HB-A43Z-01A (aliquot TCGA-HB-A43Z-01A-11D-A24N-09) from TCGA case TCGA-HB-A43Z, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; Age at diagnosis: 58.1 years (21,233 days).
Specimen TCGA-HB-A43Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f301056-7739-4322-a768-c764e3d3a10b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HB-A43Z-10A (Blood Derived Normal), aliquot TCGA-HB-A43Z-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ba3ad93-ffaa-4aac-b9d4-14d58d4b258a

The open-access MAF lists 60 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 41, Silent 11, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.785del p.G262Vfs*83 | Frame Shift Del (DEL) | VAF 21/30 reads (70%) | catalogued as rs879253905, COSV52677105, COSV52952688; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCA13 | c.12460G>A p.V4154M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV71292234; called by muse, mutect2, varscan2
- CACNA1B | c.3710C>T p.S1237L | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as rs754545679, COSV53119020; called by muse, mutect2, varscan2
- DNAH5 | c.12211C>A p.R4071S | Missense Mutation (SNP) | VAF 64/105 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as rs771514271, COSV54216575; called by muse, varscan2
- DNAH5 | c.9688G>T p.E3230* | Nonsense Mutation (SNP) | VAF 46/141 reads (33%) | catalogued as COSV54203076; called by muse, mutect2, varscan2
- DYSF | c.3688G>A p.D1230N | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754564902, COSV50271232; called by muse, mutect2, varscan2
- DZIP1 | c.1738G>C p.E580Q (on ENST00000347108; = p.E561Q on NM_014934.5) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV61270849; called by muse, mutect2, varscan2
- EFTUD2 | c.2575C>T p.Q859* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV53655974; called by muse, mutect2, varscan2
- FAF2 | c.483+2T>A p.X161_splice | Splice Site (SNP) | VAF 40/61 reads (66%) | catalogued as COSV99990372; called by muse, mutect2, varscan2
- FGR | c.572G>T p.R191I | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV64969807; called by muse, mutect2, varscan2
- GNAZ | c.723+1G>C p.X241_splice | Splice Site (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99320609; called by muse, mutect2, varscan2
- KLKB1 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 48/61 reads (79%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs753850802, COSV52996284; called by muse, mutect2, varscan2
- KNTC1 | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs151068294; called by muse, mutect2, varscan2
- KRT27 | c.781C>T p.R261* | Nonsense Mutation (SNP) | VAF 22/36 reads (61%) | catalogued as COSV56972287; called by muse, mutect2, varscan2
- MS4A14 | c.460del p.L154Ffs*57 | Frame Shift Del (DEL) | VAF 32/74 reads (43%) | catalogued as COSV100280589; called by mutect2, pindel, varscan2
- SARS1 | c.190A>G p.I64V | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.268); catalogued as rs749864964; called by muse, mutect2, varscan2
- SSTR3 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.162); catalogued as rs1354652511, COSV60730335; called by muse, mutect2, varscan2
- TMC7 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs771924631, COSV58583016; called by muse, mutect2, varscan2
- WHRN | c.916A>G p.I306V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99470084; called by muse, mutect2
- ZNF267 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT tolerated (0.17); PolyPhen benign (0.44); catalogued as rs949045331; called by muse, mutect2, varscan2
- ZNF552 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV66971909; called by muse, mutect2, varscan2
- ANXA10 | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CARD14 | c.1334G>T p.C445F | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARMIL2 | c.1618G>A p.V540M | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CEL | c.743G>A p.S248N (on ENST00000673714; = p.S245N on NM_001807.6) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.584); called by muse, varscan2
- CHD8 | c.6110C>A p.T2037N (on ENST00000646647 / NM_001170629.2; = p.T1758N on NM_020920.4) | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CLEC4G | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- HEPH | c.1903G>C p.D635H (on ENST00000343002; = p.D368H on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/86 reads (85%) | SIFT tolerated (0.06); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- IQGAP1 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KIF6 | c.1827A>T p.E609D | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MST1R | c.1597T>A p.C533S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- NIBAN2 | c.875C>G p.S292C | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NKD2 | c.743T>A p.L248Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NUDT11 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OR2G6 | c.325T>C p.S109P | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCDHA3 | c.1001G>A p.C334Y | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDGFD | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PHYKPL | c.545A>T p.H182L | Missense Mutation (SNP) | VAF 57/87 reads (66%) | SIFT tolerated (0.26); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- PLEKHO2 | c.1385G>A p.R462K | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R14C | c.241C>G p.L81V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRB3 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 26/85 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SERPINH1 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- TMEM134 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRIB2 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TRRAP | c.10324A>C p.K3442Q (on ENST00000359863 / NM_001244580.1; = p.K3413Q on NM_003496.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TTN | c.9276A>T p.K3092N (on ENST00000591111; = p.K3046N on NM_003319.4) | Missense Mutation (SNP) | VAF 35/62 reads (56%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFPM2 | c.2167T>C p.S723P | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.255); called by muse, mutect2
- ZNF236 | c.1052C>G p.S351C | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- ZNF606 | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by mutect2, varscan2
- AQP4 | c.909C>T p.D303= | Silent (SNP) | VAF 23/131 reads (18%) | catalogued as rs747485548, COSV101270582; called by muse, mutect2, varscan2
- AUH | c.621G>A p.L207= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs1252429835; called by muse, mutect2, varscan2
- CCDC146 | c.2298G>A p.K766= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV53550601, COSV99593036; called by muse, mutect2, varscan2
- FRAS1 | c.8190T>C p.D2730= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99350382; called by muse, mutect2
- GRN | c.1620C>A p.G540= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- LRP1B | c.10275G>A p.E3425= | Silent (SNP) | VAF 19/39 reads (49%) | called by muse, mutect2, varscan2
- MSX2 | c.675C>A p.P225= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- PAPPA | c.3057C>T p.F1019= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs775538278, COSV60282387; called by muse, mutect2, varscan2
- SLC28A3 | c.919C>T p.L307= | Silent (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- TBC1D2B | c.1410G>A p.A470= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as rs201179221, COSV56038989; called by muse, mutect2, varscan2
- ZFHX3 | c.4176G>A p.P1392= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs200609704, COSV51716501, COSV51730167; called by muse, mutect2, varscan2
